Somatic mutation profile of tumor specimen TCGA-MZ-A6I9-01A (aliquot TCGA-MZ-A6I9-01A-11D-A31L-08) from TCGA case TCGA-MZ-A6I9, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; Tumor grade: G2; Age at diagnosis: 68.3 years (24,939 days).
Specimen TCGA-MZ-A6I9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a7e82f3-85c2-444c-82b5-2d5ced795569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MZ-A6I9-10A (Blood Derived Normal), aliquot TCGA-MZ-A6I9-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/397ef3ca-1534-4a6f-bb03-5c42b28c6272

The open-access MAF lists 35 somatic variants for this specimen: 22 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 14, Silent 13, Nonsense Mutation 3, In Frame Del 2, Frame Shift Del 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C19orf47 | c.1098G>C p.Q366H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100775003; called by muse, mutect2, varscan2
- CCDC92 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as rs771790655, COSV99435042; called by muse, mutect2, varscan2
- CDC123 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 25/101 reads (25%) | catalogued as rs139964730; called by muse, mutect2, varscan2
- CLUH | c.1744G>A p.E582K (on ENST00000435359; = p.E620K on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as rs763046951, COSV101425585; called by muse, varscan2
- CUBN | c.4814C>G p.P1605R | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100911780; called by muse, mutect2, varscan2
- DEUP1 | c.697G>C p.A233P | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV99976472; called by muse, mutect2, varscan2
- FOXM1 | c.1044G>T p.E348D | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100700773; called by muse, mutect2
- GGT6 | c.227G>C p.R76T | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV99625121; called by muse, mutect2, varscan2
- MACF1 | c.9853T>C p.S3285P | Missense Mutation (SNP) | VAF 37/133 reads (28%) | catalogued as COSV99240263; called by muse, mutect2, varscan2
- NIPSNAP3B | c.272-1G>C p.X91_splice | Splice Site (SNP) | VAF 6/36 reads (17%) | catalogued as COSV101044365; called by muse, mutect2
- PIK3CD | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100739867; called by muse, mutect2, varscan2
- PRPF18 | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100186922; called by muse, mutect2, varscan2
- RAG1 | c.1859A>G p.E620G | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100200566; called by muse, mutect2, varscan2
- SELENOP | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 23/109 reads (21%) | catalogued as rs1412755586, COSV100736674; called by muse, mutect2, varscan2
- SLC35D2 | c.205A>G p.I69V | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV99480552; called by muse, mutect2, varscan2
- SMAD6 | c.954C>T p.D318= | Splice Region (SNP) | VAF 4/11 reads (36%) | catalogued as rs779204615, COSV56596067; called by muse, varscan2
- TENM1 | c.7514G>A p.R2505Q | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.049); catalogued as rs764579928, COSV100948736; called by muse, mutect2, varscan2
- ZNF135 | c.1567G>T p.E523* (on ENST00000313434 / NM_001289401.2; = p.E535* on NM_003436.4) | Nonsense Mutation (SNP) | VAF 23/95 reads (24%) | catalogued as COSV100536360, COSV57886140; called by muse, mutect2, varscan2
- ZNF648 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.024); catalogued as COSV100374352; called by muse, mutect2, varscan2
- DNAH1 | c.11948_11953del p.G3983_R3984del | In Frame Del (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- PNPLA8 | c.1118del p.T373Kfs*14 | Frame Shift Del (DEL) | VAF 69/344 reads (20%) | called by mutect2, pindel, varscan2
- ZNF155 | c.960_968del p.C321_K323del | In Frame Del (DEL) | VAF 17/115 reads (15%) | called by mutect2, pindel, varscan2
- ANK1 | c.1006C>T p.L336= | Silent (SNP) | VAF 12/230 reads (5%) | catalogued as COSV99223445; called by muse, mutect2
- EMC1 | c.2625G>A p.K875= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100916393; called by muse, mutect2, varscan2
- FCN3 | c.741G>C p.V247= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV99585121, COSV99585514; called by muse, mutect2, varscan2
- FOXR2 | c.153C>A p.V51= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV100189350; called by muse, mutect2, varscan2
- HAND1 | c.552C>T p.H184= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV99163938; called by muse, mutect2
- IGHV1-58 | c.210C>T p.I70= | Silent (SNP) | VAF 7/135 reads (5%) | catalogued as rs947808103; called by muse, mutect2
- MAD1L1 | c.999C>T p.D333= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99764803; called by muse, mutect2, varscan2
- MINPP1 | c.507C>T p.F169= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV64355987; called by muse, mutect2, varscan2
- MYH6 | c.960C>T p.S320= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs376547858; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRUNE2 | c.162G>C p.L54= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV100942717; called by muse, mutect2, varscan2
- PUS10 | c.1236G>A p.K412= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as COSV100369301; called by muse, varscan2
- RFX5 | c.1408C>A p.R470= | Silent (SNP) | VAF 105/477 reads (22%) | catalogued as rs79106593, COSV100923789; called by muse, mutect2, varscan2
- SNX31 | c.849A>G p.E283= | Silent (SNP) | VAF 12/198 reads (6%) | catalogued as COSV100309803; called by muse, mutect2
